Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AAW3, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AAW3-01A (Primary Tumor).

ICD O-3
Carcinoma, hepatocellular NOS
Site: Liver C22.0
8170/3
9/24/2014

DIAGNOSIS:

Liver, right, posterior sectionectomy:

Hepatocellular carcinoma, S7

- 1) Post-chemoembolization status: absent
- 2) Size of tumor: 3.1x2.7x2.5cm
- 3) Gross type: nodular with perinodal extension type
- 4) Satellite nodule: absent
- 5) Histologic type: trabecular and pseudoglandular
- 6) Cell type: classic cell group
- 7) Edmondson and Steiner's histologic grade:
The worst differentiation: 3
The major differentiation: 2
- 8) Fatty change: absent
- 9) Hemorrhage/peliosis: absent
- 10) Tumor necrosis: absent
- 11) Vascular invasion(microscopic): absent
- 12) Capsule formation: partial
- 13) Infiltration of capsule: present
- 14) Septal formation: present
- 15) Involvement of a major branch of the portal vein: absent
- 16) Involvement of a major branch of the hepatic vein: absent
- 17) Bile duct invasion: absent
- 18) Serosal invasion: absent
- 19) Surgical margin: clear (safety margin: 1.0cm)
- 20) Lymph node: no metastasis in 2 lymph nodes
(pericholedochal LN: 0/2)
- 21) Intrahepatic metastasis: absent
- 22) Multicentric occurrence: absent
- 23) Pathologic stage: AJCC (pT1), (pT2)
- 24) Related biopsy: none
- 25) Additional pathologic findings
- a) Chronic hepatitis: absent
- b) Cirrhosis: absent
- c) Dysplasia: absent

Soft tissue, small bowel mesentery, excision:

Lipoma

Gallbladder, cholecystectomy:

No diagnostic abnormalities recognized

Source: NCI Genomic Data Commons file 87375eb5-3114-441e-bcc7-6e57989ad7d5 (TCGA-DD-AAW3.882E141C-D3AB-4EF8-A26E-D5D3F75443B6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).